Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7290, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7290-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:
OF [REDACTED] HAS BEEN CHANGED.

BRAIN, RIGHT TEMPORAL LOBE, BIOPSY: SMALL CELL GLIOMA (TO BE FURTHER CLASSIFIED; SEE MICROSCOPIC DESCRIPTION).

REVISED PATHOLOGICAL DIAGNOSIS:

BRAIN, RIGHT TEMPORAL LOBE, BIOPSY: ASTROCYTOMA, ANAPLASTIC, DIFFUSELY INFILTRATING.

Operation/Specimen: Brain, right temporal lobe.

Clinical History and Pre-Op Dx: Patient with several month history of visual disturbances and headaches who has a CT scan lesion involving the right temporal lobe and extending across the midline to the left hemisphere. The differential diagnosis is between lymphoma and a glioma.

INTRAOPERATIVE CONSULTATION: Astrocytoma, anaplastic [REDACTED]
[REDACTED].

GROSS PATHOLOGY: Specimen received in a container labeled with the patient's name and MRN. A portion of this specimen is used for the intraoperative consultation and for fixation in glutaraldehyde for eventual electron microscopy. The total amount of tissue removed equals approximately 5.0 g and all remaining fragments are submitted in six tissue cassettes.

MICROSCOPIC: Fragments of cerebral cortex and underlying white matter showing multiple, focal and diffuse infiltrates by small neoplastic cells that in general lack differentiation. In many areas the cells surround individual neurons and in small sites they show some degree of cytoplasmic differentiation which appears similar to that of an astrocyte. There are multiple perivascular nests of neoplastic cells. Areas of coagulation necrosis or atypical mitosis are not readily identified, however the general impression is that this pattern of tissue infiltrate may represent distant extension of a rather aggressive type of undifferentiated neoplasm.

In summary, the impression formed at the time of the intraoperative consultation that this represents a small cell glioma with very anaplastic features is sustained by the evidence available at this

[page 2 of 2]
time. In an attempt to further identify the genetic derivation of these cells additional sections will be cut and reacted with various antisera as follows: GFAP, LCA, EMA, CK-6, Synaptophysin and MIB-1.

In addition one of the samples taken for electron microscopy will be evaluated.

An addendum will be issued when all of these are completed.

COMMENT: Additional sections were cut from several blocks and reacted with the following antisera: LCA, EMA, CK-6, and Synaptophysin; these are negative in all the neoplastic cells. These results are interpreted as confirming the initial impression that the derivation of these cells is not from lymphocytes, neuronal elements, or epithelial cells. GFAP is expressed by approximately 20% of the neoplastic cells.

MIB-1: This protein is expressed by diverse percentages of cells in various locations; however, the mean percentage of cells expressing this protein is estimated to be about 10%.

Sections evaluated with the electron microscope confirm the impression that the cytoplasmic features as well as the nuclei of most neoplastic cells are compatible with those characteristic of a neoplastic astrocyte.

A letter from Dr. [REDACTED] is in agreement with the diagnosis of anaplastic astrocytoma. The involuntary delay in the issuance of this final report represents a combination of simultaneous events including my absence from the department for over two weeks, and the fact that the slides were mailed to Dr. [REDACTED] for consultation before dictating the addendum, and his reply was not opportunely delivered to the pathologist on call during my absence.

[REDACTED]

[REDACTED]

TISSUE COMMITTEE CODE: [REDACTED]
BILLING CODES [REDACTED]

Source: NCI Genomic Data Commons file ac6028d9-01b4-4d90-b044-8c8ee8d389a8 (TCGA-DU-7290.06977359-42D7-453C-9ED3-46A58A7F5726.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).